Gene-level copy-number profile of tumor specimen HTMCP-02-01-01255-01A from CGCI case HTMCP-02-01-01255, project CGCI-HTMCP-LC (HIV+ Tumor Molecular Characterization Project - Lung Cancer). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage I.
Specimen HTMCP-02-01-01255-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ea2282bb-d12b-4c5e-a8be-8be9556b4979.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-02-01-01255-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,861 have no estimate.
https://portal.gdc.cancer.gov/files/55889f9c-6d2d-4faa-9e21-58faf54be0d2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 200; copy number 1: 16,675; copy number 2: 34,094; copy number 3: 4,543; copy number 4: 2,602; copy number 5: 234; copy number 6: 11; copy number 7: 400; copy number 8: 1; copy number 10: 2.

Homozygous deletions (total copy number 0; autosomes only): 199 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:363,370–385,795, 1 gene (within-gene range 0–2): CHL1-AS1.
- chr3:58,490,830–71,754,229, 120 genes (within-gene range 0–1) (broad region; genes not listed).
- chr5:60,429,903–60,548,813, 6 genes (within-gene range 0–1): AC109486.1, SETP21, AC109486.2, PART1, AC109486.3, AC016591.1.
- chr5:138,115,175–138,178,953, 4 genes (within-gene range 0–1): NME5, RNU6-460P, RNU6-888P, BRD8.
- chr8:12,182,096–12,400,366, 12 genes (within-gene range 0–1): FAM86B1, AC145124.1, ENPP7P12, DEFB131D, DEFB130A, RNA5SP254, DEFB108E, ZNF705CP, FAM66A, AC087203.1, AC087203.2, DEFB109A.
- chr9:60,914,407–61,662,690, 16 genes: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3, SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA, AL935212.1.
- chr9:61,789,143–62,711,398, 30 genes: RN7SL722P, FAM27C, AL391987.2, AL391987.1, AL391987.4, AL391987.3, Y_RNA, FAM242E, CR769775.1, AL590399.4, AL590399.3, AL590399.6, SNORA70, RN7SL544P, AL590399.1, FGF7P6, AL590399.5, AL590399.2, BX664725.1, LINC01189, FGF7P7, BX005266.2, BX005266.1, CNTNAP3P5, RBPJP7, RAB28P2, BX005266.3, ATP5F1AP7, SDR42E1P3, FKBP4P7.
- chr19:12,195,015–12,294,887, 4 genes (within-gene range 0–1): AC012618.3, ZNF44, AC012618.1, AC012618.2.
- chr21:9,053,122–9,368,775, 6 genes: CR392039.4, TEKT4P2, SOWAHCP2, CR392039.2, CR381653.1, SNX18P12.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 648 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:128,619,969–128,681,075, 3 genes, copy number 5: RPN1, Metazoa_SRP, POU5F1P6.
- chr3:163,109,152–163,361,563, 1 gene, copy number 6 (within-gene range 4–6): LINC01192.
- chr3:163,455,568–164,831,480, 6 genes, copy number 6: AC079910.1, RNU7-82P, AC084017.1, MIR1263, LINC01323, LINC01324.
- chr3:166,160,021–186,362,234, 344 genes, copy number 7–10 (broad region; genes not listed).
- chr5:37,286,449–37,377,971, 4 genes, copy number 5: AC025449.1, NUP155, RNU7-75P, AC117532.1.
- chr8:36,784,324–36,936,125, 1 gene, copy number 7 (within-gene range 3–7): KCNU1.
- chr8:36,887,456–37,095,390, 4 genes, copy number 5–7: TPT1P8, AC090453.1, AC092818.1, SMARCE1P4.
- chr8:37,421,341–41,625,001, 102 genes, copy number 5 (broad region; genes not listed).
- chr8:46,549,089–48,385,049, 45 genes, copy number 5: HSPA8P13, ASNSP1, AC104576.1, ASNSP4, AC021451.1, TRIM60P15, LINC00293, MTND2P38, MTND1P7, RNU6-656P, MTCYBP20, MTND6P20, AC091163.3, AC091163.1, AC091163.2, MAPK6P4, RN7SKP32, AC120036.1, AC120036.5, RNU6-819P, RPL10AP2, NDUFA5P12, AC120036.3, AC120036.4, ATP6V1G1P2, AC120036.2, IGLV8OR8-1, SPIDR, AC024451.2, AC024451.4, AC024451.1, AC024451.3, RNU6-665P, CEBPD, PRKDC, Y_RNA, AC021236.1, MCM4, RNU6-519P, UBE2V2, AC104989.1, IDI1P2, RNU6-295P, RNA5SP531, RPL29P19.
- chr16:27,066,707–29,670,876, 121 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr22:17,137,511–17,730,855, 17 genes, copy number 5: HDHD5, HDHD5-AS1, ADA2, AC005300.1, FAM32BP, CECR3, CECR9, RN7SL843P, CECR2, FO681548.1, CLCP1, DNAJA1P6, AC007666.2, SLC25A18, AC007666.1, ATP6V1E1, BCL2L13.

Autosomal genes at a single copy (total copy number 1): 13,972. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
